Somatic mutation profile of tumor specimen ALCH-ADWH-TTP1-A (aliquot ALCH-ADWH-TTP1-A-1-0-D-A582-36) from ALCHEMIST case ALCH-ADWH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.8 years (22,924 days).
Specimen ALCH-ADWH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4e4b43f-8bf9-492e-8ce9-0c1e0addecc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADWH-NB1-A (Blood Derived Normal), aliquot ALCH-ADWH-NB1-A-1-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22140735-1b2d-40a3-bcc2-5a095d50200f

The open-access MAF lists 378 somatic variants for this specimen: 270 protein-altering or splice-affecting, 60 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 233, Silent 60, Nonsense Mutation 25, Intron 19, RNA 13, 5'UTR 6, Splice Site 6, Frame Shift Del 4, 5'Flank 4, 3'Flank 3, 3'UTR 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.3127G>T p.V1043L | Missense Mutation (SNP) | VAF 24/339 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV53242734; called by muse, mutect2
- ADGRD1 | c.2268-1G>T p.X756_splice | Splice Site (SNP) | VAF 23/195 reads (12%) | catalogued as COSV55453602; called by muse, varscan2
- ADGRG4 | c.6978C>A p.Y2326* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | catalogued as COSV54968998; called by muse, mutect2, varscan2
- AKAP6 | c.5441G>T p.R1814I | Missense Mutation (SNP) | VAF 46/466 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV55232388; called by muse, mutect2
- ATRNL1 | c.3983G>T p.R1328L | Missense Mutation (SNP) | VAF 40/371 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as COSV58084608; called by muse, mutect2, varscan2
- BRINP3 | c.2147C>A p.P716H | Missense Mutation (SNP) | VAF 65/531 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV66539544; called by muse, mutect2, varscan2
- CDH8 | c.1570G>T p.D524Y | Missense Mutation (SNP) | VAF 57/877 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100183252, COSV54903538; called by muse, mutect2
- CHD9 | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 35/516 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1482794285; called by muse, mutect2
- CHIT1 | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 47/675 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1176805685; called by muse, mutect2
- CLASRP | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs749540610; called by muse, varscan2
- CNGB3 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 50/698 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs758828078; called by muse, mutect2
- CNTNAP4 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 31/387 reads (8%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as rs1344229735; called by muse, mutect2
- CYB5RL | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 33/614 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs763985375; called by muse, mutect2
- DNAH14 | c.3896G>A p.R1299H (on ENST00000445597; = p.R1709H on NM_001367479.1) | Missense Mutation (SNP) | VAF 60/418 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs143916022; called by muse, mutect2, varscan2
- DPRX | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs201734272; called by muse, mutect2, varscan2
- DYSF | c.5296G>T p.E1766* | Nonsense Mutation (SNP) | VAF 26/344 reads (8%) | catalogued as CM053211; called by muse, mutect2
- EGFL6 | c.195C>A p.C65* | Nonsense Mutation (SNP) | VAF 31/120 reads (26%) | catalogued as rs777290359, COSV63060270; called by muse, mutect2, varscan2
- EPC1 | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 21/372 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as COSV53927598; called by muse, mutect2
- FAM151A | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 24/253 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs781597271; called by muse, mutect2
- FASN | c.5515G>T p.A1839S | Missense Mutation (SNP) | VAF 45/277 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV60750240; called by muse, mutect2, varscan2
- FGF13 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 57/349 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768293112, COSV100264529; called by muse, mutect2, varscan2
- FOXO4 | c.1299G>A p.M433I | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1425779738, COSV58576319; called by muse, mutect2
- FSCB | c.2412G>T p.Q804H | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as COSV61216594; called by muse, mutect2
- GAD2 | c.808C>A p.L270I | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV52171054; called by muse, mutect2
- GDNF | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 126/698 reads (18%) | catalogued as COSV58479130; called by muse, mutect2, varscan2
- GEM | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 62/710 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99891722; called by muse, mutect2
- GPR148 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs781175164; called by muse, mutect2, varscan2
- GPR37 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1380125999; called by muse, mutect2, varscan2
- JRKL | c.1362A>T p.Q454H | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as rs762279754; called by muse, mutect2
- JUP | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 52/448 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV60280038; called by muse, mutect2, varscan2
- KCNH4 | c.2645G>T p.R882L | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs1169628526; called by muse, mutect2
- KCNH8 | c.1318G>A p.V440I | Missense Mutation (SNP) | VAF 32/472 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs775385172; called by muse, mutect2
- KIF21A | c.2471G>T p.R824L (on ENST00000361418 / NM_001378440.1; = p.R811L on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 878/2301 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.809); catalogued as COSV62774467; called by muse, mutect2, varscan2
- L1TD1 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 42/394 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1252662779; called by muse, mutect2, varscan2
- LHX8 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 62/826 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV53959152, COSV53961081; called by muse, mutect2
- LRRC7 | c.4258G>A p.G1420R (on ENST00000651989 / NM_001370785.2; = p.G1340R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/271 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.777); catalogued as COSV99225350; called by muse, mutect2
- MAEA | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 25/334 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1282574958; called by muse, mutect2
- MAGI2 | c.1651A>G p.I551V | Missense Mutation (SNP) | VAF 56/742 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.041); catalogued as rs1356490241; called by muse, mutect2
- MAN2A2 | c.2677G>A p.D893N | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs773866909; called by muse, mutect2
- MUC16 | c.17980C>T p.L5994F | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs747436072; called by muse, mutect2, varscan2
- NAV3 | c.2375G>T p.R792M | Missense Mutation (SNP) | VAF 49/499 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99886810; called by muse, mutect2
- NCKAP5 | c.3923G>T p.R1308I | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58449157; called by muse, mutect2
- NF1 | c.7504G>T p.G2502* (on ENST00000358273 / NM_001042492.3; = p.G2481* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 83/648 reads (13%) | catalogued as CM134547; called by muse, mutect2, varscan2
- OR10H5 | c.818C>A p.T273N | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as rs774972468; called by muse, mutect2, varscan2
- OR10J5 | c.891G>C p.K297N | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV58386260, COSV58386328; called by muse, mutect2
- OR10K2 | c.225C>A p.F75L | Missense Mutation (SNP) | VAF 55/519 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs139262696; called by muse, mutect2, varscan2
- OR14K1 | c.348G>C p.M116I | Missense Mutation (SNP) | VAF 56/571 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV99315062; called by muse, mutect2, varscan2
- OR52N4 | c.99C>A p.F33L | Missense Mutation (SNP) | VAF 53/605 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV57890728; called by muse, mutect2
- OR56A3 | c.178C>G p.H60D | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100290345; called by muse, mutect2
- OR5D16 | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 38/344 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65723119; called by muse, mutect2, varscan2
- OR5L2 | c.155G>T p.S52I | Missense Mutation (SNP) | VAF 38/428 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV101004433; called by muse, mutect2
- OR5M11 | c.533G>T p.C178F | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101602024; called by muse, mutect2
- OR8B8 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs775943430, COSV60145081; called by muse, mutect2
- OTOF | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 15/482 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1269547326; called by muse, mutect2
- PARP8 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 40/520 reads (8%) | catalogued as rs1046495888; called by muse, mutect2
- PCDHA3 | c.1433C>A p.S478Y | Missense Mutation (SNP) | VAF 94/954 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.213); catalogued as COSV63543133; called by muse, mutect2
- PCDHB10 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 65/814 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs781819470; called by muse, mutect2
- PCDHB9 | c.2338G>T p.G780W | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.757); catalogued as rs1403438365; called by muse, mutect2
- PCDHGA5 | c.179del p.A60Gfs*18 | Frame Shift Del (DEL) | VAF 26/233 reads (11%) | catalogued as COSV54022477; called by mutect2, pindel, varscan2
- PCDHGB2 | c.2381G>A p.G794E | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV53963675; called by muse, mutect2
- PEG3 | c.2728G>A p.G910R | Missense Mutation (SNP) | VAF 19/263 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.692); catalogued as COSV55650954; called by muse, mutect2
- PKHD1L1 | c.10817T>C p.L3606S | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1370606282; called by muse, mutect2
- PPP1R32 | c.1252A>T p.S418C | Missense Mutation (SNP) | VAF 39/356 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs1486773371; called by muse, mutect2, varscan2
- PSMD6 | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs373849478; called by muse, mutect2
- PXDNL | c.2252G>T p.R751L | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62484723; called by muse, mutect2, varscan2
- PXDNL | c.774del p.G259Efs*33 | Frame Shift Del (DEL) | VAF 41/366 reads (11%) | catalogued as COSV62483007; called by mutect2, pindel, varscan2
- RASGRP2 | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 54/477 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62449049; called by muse, mutect2, varscan2
- RBM10 | c.2179G>T p.G727* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as COSV61312326; called by muse, mutect2, varscan2
- RIC3 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 43/385 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs761145811; called by muse, mutect2, varscan2
- RIMS2 | c.2342G>A p.R781K (on ENST00000666250 / NM_001348490.2; = p.R589K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/247 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51727156; called by muse, mutect2
- RYR2 | c.13202G>T p.G4401V | Missense Mutation (SNP) | VAF 143/1121 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV63716242; called by muse, mutect2, varscan2
- SCN10A | c.3654G>T p.W1218C | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71861715; called by muse, mutect2, varscan2
- SCN1A | c.3734G>C p.R1245P (on ENST00000303395 / NM_001202435.3; = p.R1234P on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/361 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM067003, COSV57689039; called by muse, mutect2
- SEZ6L | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); catalogued as rs1274318543; called by muse, mutect2, varscan2
- SFMBT2 | c.391G>T p.V131L | Missense Mutation (SNP) | VAF 29/336 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); catalogued as rs1251850601, COSV62806679, COSV62813901; called by muse, mutect2
- SH3BP5L | c.967G>T p.G323W | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63539445; called by muse, mutect2
- SMYD1 | c.1294C>A p.P432T | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV70225274; called by muse, mutect2, varscan2
- SP140L | c.1075T>A p.C359S | Missense Mutation (SNP) | VAF 21/312 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54746926; called by muse, mutect2
- SPRY3 | c.207C>A p.C69* | Nonsense Mutation (SNP) | VAF 45/417 reads (11%) | catalogued as COSV100249588; called by muse, mutect2, varscan2
- SYNE1 | c.20002G>T p.A6668S (on ENST00000367255 / NM_182961.4; = p.A6597S on NM_033071.3) | Missense Mutation (SNP) | VAF 67/726 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as rs770873356; called by muse, mutect2
- TMEM176A | c.173G>T p.W58L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1443591875; called by muse, mutect2, varscan2
- TRO | c.3986G>T p.R1329I | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV51503669; called by muse, mutect2, varscan2
- TRPM5 | c.1895T>C p.F632S | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV50151927; called by muse, mutect2, varscan2
- TTC24 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs746684263; called by muse, mutect2, varscan2
- UBXN10 | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 54/594 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV66771981; called by muse, mutect2
- WDR59 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 37/368 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759015915; called by muse, mutect2, varscan2
- ZBTB5 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 21/238 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV100312978; called by muse, mutect2
- ZNF75D | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 92/399 reads (23%) | catalogued as rs1556419972; called by muse, mutect2, varscan2
- ABCA13 | c.14760G>T p.E4920D | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, varscan2
- ABCC11 | c.2743C>T p.P915S | Missense Mutation (SNP) | VAF 28/450 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ACAA1 | c.82A>G p.S28G | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSM1 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- ADAMTS12 | c.3795C>A p.N1265K | Missense Mutation (SNP) | VAF 129/586 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTSL3 | c.148A>T p.T50S | Missense Mutation (SNP) | VAF 39/516 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); called by muse, mutect2
- ADGRG4 | c.3134C>A p.T1045K | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- ADGRG6 | c.1367A>T p.H456L | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.114); called by muse, mutect2
- ANKH | c.685G>T p.G229W | Missense Mutation (SNP) | VAF 56/872 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKMY2 | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 36/486 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.338); called by muse, mutect2
- ANKRD30B | c.617G>A p.C206Y | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.354); called by muse, mutect2
- APOB | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 57/740 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- APOOL | c.803G>T p.S268I | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF4 | c.224A>C p.Q75P | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); called by muse, mutect2
- ART5 | c.164A>T p.K55M | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ASPHD2 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ASTN2 | c.1751+1G>T p.X584_splice (on ENST00000313400 / NM_001365069.1; = p.X533_splice on NM_014010.5) | Splice Site (SNP) | VAF 40/307 reads (13%) | called by muse, mutect2, varscan2
- ATP8B4 | c.2631C>A p.F877L | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCR | c.1488G>T p.L496F | Missense Mutation (SNP) | VAF 24/367 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- BCR | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 24/365 reads (7%) | called by muse, mutect2
- BIRC6 | c.3541A>T p.I1181F | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- C14orf28 | c.108A>T p.K36N | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.277); called by muse, mutect2
- C19orf18 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); called by muse, mutect2
- CACNA2D3 | c.1914C>A p.G638= | Splice Region (SNP) | VAF 25/371 reads (7%) | called by muse, mutect2
- CAPN6 | c.838G>T p.V280F | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CCBE1 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 23/509 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- CD226 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 38/721 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CDK14 | c.601C>T p.H201Y (on ENST00000380050 / NM_001287135.2; = p.H183Y on NM_012395.3) | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2
- CENPJ | c.3461G>T p.S1154I | Missense Mutation (SNP) | VAF 66/650 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2
- CLUL1 | c.12G>T p.W4C | Missense Mutation (SNP) | VAF 19/275 reads (7%) | PolyPhen possibly damaging (0.878); called by muse, mutect2
- CNNM2 | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 23/261 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.782); called by muse, mutect2
- CNTN4 | c.1683G>T p.L561F | Missense Mutation (SNP) | VAF 81/1098 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL3A1 | c.2363C>A p.P788Q | Missense Mutation (SNP) | VAF 89/964 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.289); called by muse, mutect2
- COL6A6 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 41/451 reads (9%) | called by muse, mutect2
- CPA3 | c.236A>T p.Q79L | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.253); called by muse, mutect2
- CSMD3 | c.8737G>T p.A2913S (on ENST00000297405 / NM_001363185.1; = p.A2744S on NM_052900.3) | Missense Mutation (SNP) | VAF 73/606 reads (12%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DAAM2 | c.914T>G p.L305R | Missense Mutation (SNP) | VAF 16/463 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DCT | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 38/413 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DMXL1 | c.4992G>T p.M1664I | Missense Mutation (SNP) | VAF 52/592 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- DPY19L2 | c.1976C>A p.P659Q | Missense Mutation (SNP) | VAF 501/966 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EIPR1 | c.442G>T p.G148W | Missense Mutation (SNP) | VAF 25/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ENTPD5 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2
- ESX1 | c.716C>A p.P239Q | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EVX1 | c.940T>C p.S314P | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.222); called by muse, mutect2
- FAM114A2 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 90/652 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, varscan2
- FAM135B | c.4142C>A p.A1381D | Missense Mutation (SNP) | VAF 135/966 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM47C | c.2234C>A p.P745H | Missense Mutation (SNP) | VAF 74/354 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- FARSB | c.669C>G p.I223M | Missense Mutation (SNP) | VAF 17/540 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- FAT1 | c.3610G>C p.D1204H | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAT3 | c.8153C>A p.A2718E | Missense Mutation (SNP) | VAF 42/412 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FBXW11 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 34/397 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FCGR3B | c.210G>T p.Q70H | Missense Mutation (SNP) | VAF 70/642 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- FCRL4 | c.1252G>T p.V418F | Missense Mutation (SNP) | VAF 70/829 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.043); called by muse, mutect2
- FIGNL2 | c.1150G>T p.D384Y | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- GASK1A | c.1361G>T p.R454M | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, varscan2
- GBF1 | c.1643A>G p.Y548C (on ENST00000369983 / NM_001377137.1; = p.Y547C on NM_004193.3) | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GFY | c.157A>G p.K53E | Missense Mutation (SNP) | VAF 83/586 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- GIMAP8 | c.218T>A p.I73K | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.062); called by muse, mutect2
- GLDC | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 125/1128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOLM2 | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 37/358 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2
- GPAT2 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 37/316 reads (12%) | called by muse, mutect2, varscan2
- GPR12 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 52/509 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR83 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); called by muse, mutect2
- GPR83 | c.588G>C p.M196I | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.178); called by muse, mutect2
- GPX5 | c.232C>G p.Q78E | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.695); called by muse, mutect2
- GRIA1 | c.1735A>T p.S579C | Missense Mutation (SNP) | VAF 45/323 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- GRIN1 | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 35/388 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRIN2D | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- GRIN3B | c.503C>A p.A168E | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.011); called by muse, mutect2
- HAVCR2 | c.59-1G>A p.X20_splice | Splice Site (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- HCRTR2 | c.579C>A p.C193* | Nonsense Mutation (SNP) | VAF 34/533 reads (6%) | called by muse, mutect2
- HDC | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 39/475 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- HEG1 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 72/687 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HERC2 | c.11066G>T p.W3689L | Missense Mutation (SNP) | VAF 39/413 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HERC5 | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 15/310 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2
- HK3 | c.1618G>T p.A540S | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMMR | c.1414G>C p.D472H | Missense Mutation (SNP) | VAF 42/462 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); called by muse, mutect2
- HS3ST2 | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- HSDL1 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 15/538 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2
- IDH3G | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGDCC3 | c.234T>A p.N78K | Missense Mutation (SNP) | VAF 38/461 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- IGHV3-66 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 42/745 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.763); called by muse, mutect2
- IL5RA | c.854A>T p.Q285L | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); called by muse, mutect2
- IRS4 | c.1507G>A p.G503S | Missense Mutation (SNP) | VAF 53/366 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ITIH5 | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- ITPR3 | c.2137C>T p.Q713* | Nonsense Mutation (SNP) | VAF 24/168 reads (14%) | called by muse, mutect2, varscan2
- KALRN | c.8818C>A p.P2940T (on ENST00000360013 / NM_001024660.4; = p.P1243T on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/526 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.087); called by muse, mutect2
- KIAA1328 | c.74A>T p.Q25L | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- KIF2B | c.212T>A p.I71N | Missense Mutation (SNP) | VAF 76/631 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- KMT2C | c.3006G>T p.W1002C | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LAMB2 | c.869C>G p.S290* | Nonsense Mutation (SNP) | VAF 14/326 reads (4%) | called by muse, mutect2
- LILRB2 | c.240C>A p.N80K | Missense Mutation (SNP) | VAF 66/740 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- LIMCH1 | c.468G>T p.L156F | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.124); called by muse, mutect2
- LOXL4 | c.610T>A p.C204S | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRRC30 | c.406C>A p.L136M | Missense Mutation (SNP) | VAF 27/434 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2
- LTBP4 | c.3673G>T p.G1225C (on ENST00000308370 / NM_001042544.1; = p.G1188C on NM_003573.2) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- MAGEH1 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.378); called by muse, mutect2
- MAGEL2 | c.2459C>A p.A820D | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- MAMLD1 | c.1969C>T p.Q657* | Nonsense Mutation (SNP) | VAF 89/455 reads (20%) | called by muse, mutect2, varscan2
- ME2 | c.386G>T p.R129I | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- MET | c.3594A>T p.K1198N | Missense Mutation (SNP) | VAF 95/1014 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- MGA | c.7140-2A>T p.X2380_splice (on ENST00000219905 / NM_001164273.1; = p.X2171_splice on NM_001080541.2) | Splice Site (SNP) | VAF 22/278 reads (8%) | called by muse, mutect2
- MGA | c.7140-1G>T p.X2380_splice (on ENST00000219905 / NM_001164273.1; = p.X2171_splice on NM_001080541.2) | Splice Site (SNP) | VAF 22/276 reads (8%) | called by muse, mutect2
- MMRN1 | c.1601C>A p.A534D | Missense Mutation (SNP) | VAF 32/448 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.216); called by muse, mutect2
- MS4A18 | c.715G>T p.D239Y (on ENST00000398983; = p.D241Y on NM_001354471.1) | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- MSH4 | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYH2 | c.1149T>A p.V383= | Splice Region (SNP) | VAF 47/862 reads (5%) | called by muse, mutect2
- MYL1 | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 14/367 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.514); called by muse, mutect2
- MYO18A | c.4588G>T p.E1530* | Nonsense Mutation (SNP) | VAF 58/753 reads (8%) | called by muse, mutect2
- NAALADL2 | c.492A>T p.L164F | Missense Mutation (SNP) | VAF 21/245 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- NF1 | c.934G>T p.G312* | Nonsense Mutation (SNP) | VAF 60/674 reads (9%) | called by muse, mutect2
- NFATC2 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOP9 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 56/482 reads (12%) | called by muse, varscan2
- NR0B1 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- NR1H3 | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 39/334 reads (12%) | called by muse, mutect2, varscan2
- NR3C1 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 48/641 reads (7%) | called by muse, mutect2
- NUDT22 | c.678-2A>T p.X226_splice | Splice Site (SNP) | VAF 16/148 reads (11%) | called by muse, mutect2, varscan2
- OR1S1 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 46/354 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- OR2M2 | c.66del p.P23Hfs*14 | Frame Shift Del (DEL) | VAF 22/199 reads (11%) | called by mutect2, pindel*
- OR2M4 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- OR5H2 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2
- OR5W2 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PAK5 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 62/774 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- PCOLCE2 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 48/466 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDZRN4 | c.2968C>A p.L990M (on ENST00000402685 / NM_001164595.2; = p.L732M on NM_013377.4) | Missense Mutation (SNP) | VAF 101/270 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- PGBD5 | c.958G>T p.A320S (on ENST00000525115; = p.A389S on NM_001258311.2) | Missense Mutation (SNP) | VAF 57/362 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIK3CB | c.1665G>T p.M555I | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2
- PIP4K2A | c.816G>T p.M272I | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, varscan2
- PKHD1L1 | c.10481C>A p.T3494K | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PKN2 | c.2839G>A p.D947N | Missense Mutation (SNP) | VAF 42/720 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2
- PLPPR4 | c.2075G>T p.S692I | Missense Mutation (SNP) | VAF 40/485 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- PNLIPRP1 | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.093); called by muse, mutect2
- PRDM9 | c.1657G>T p.V553F | Missense Mutation (SNP) | VAF 84/899 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2
- PTK2B | c.2924A>T p.Q975L | Missense Mutation (SNP) | VAF 41/478 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2
- RAB3GAP2 | c.3836A>G p.Y1279C | Missense Mutation (SNP) | VAF 77/701 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RAB3GAP2 | c.2555C>G p.S852* | Nonsense Mutation (SNP) | VAF 12/402 reads (3%) | called by muse, mutect2
- RAB3GAP2 | c.36G>T p.Q12H | Missense Mutation (SNP) | VAF 63/581 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- RAVER2 | c.1885G>C p.E629Q (on ENST00000294428 / NM_001366165.1; = p.E616Q on NM_018211.4) | Missense Mutation (SNP) | VAF 12/384 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2
- RHOBTB1 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 37/635 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RSPH3 | c.623G>T p.G208V (on ENST00000252655; = p.G66V on NM_031924.8) | Missense Mutation (SNP) | VAF 40/437 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2
- RTL1 | c.3541C>G p.Q1181E | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, varscan2
- RYR3 | c.663del p.H222Mfs*2 | Frame Shift Del (DEL) | VAF 65/500 reads (13%) | called by mutect2, pindel, varscan2
- RYR3 | c.3280G>T p.V1094L | Missense Mutation (SNP) | VAF 78/1008 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.189); called by muse, mutect2
- SAMD9L | c.4033G>T p.E1345* | Nonsense Mutation (SNP) | VAF 26/292 reads (9%) | called by muse, mutect2
- SCRIB | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- SDHA | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 28/542 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2
- SDK1 | c.1268A>T p.D423V | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SDK2 | c.255C>G p.H85Q | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2
- SELP | c.850C>A p.H284N | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.187); called by muse, mutect2
- SEMA4B | c.2480G>T p.R827L | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SERPINA6 | c.578C>A p.A193D | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.692); called by muse, mutect2
- SERPINB4 | c.494A>T p.D165V | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.088); called by muse, mutect2
- SFTPB | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SIRPA | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 50/651 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC14A2 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- SLIT3 | c.2773T>A p.C925S | Missense Mutation (SNP) | VAF 44/493 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- SNRPN | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SOX11 | c.967C>A p.P323T | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2
- SS18 | c.1030G>T p.G344* (on ENST00000415083 / NM_001007559.3; = p.G313* on NM_005637.3) | Nonsense Mutation (SNP) | VAF 38/492 reads (8%) | called by muse, mutect2
- STIM2 | c.1672G>T p.D558Y | Missense Mutation (SNP) | VAF 38/719 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TBX5 | c.528G>A p.M176I | Missense Mutation (SNP) | VAF 79/831 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TDRD6 | c.4702C>T p.P1568S | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.785); called by muse, mutect2
- TENM1 | c.7050C>A p.Y2350* | Nonsense Mutation (SNP) | VAF 47/326 reads (14%) | called by muse, mutect2, varscan2
- TLX3 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 47/445 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TMEM200A | c.389C>A p.P130Q | Missense Mutation (SNP) | VAF 23/308 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM200A | c.1253G>T p.S418I | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TNNI3 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TPGS1 | c.554C>A p.T185K | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TPK1 | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- TRIM58 | c.1303A>T p.T435S | Missense Mutation (SNP) | VAF 70/611 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- TTN | c.79807T>A p.C26603S (on ENST00000591111; = p.C19179S on NM_003319.4) | Missense Mutation (SNP) | VAF 50/618 reads (8%) | PolyPhen benign (0.003); called by muse, mutect2
- VGLL3 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- VIPAS39 | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 74/972 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- VPS13D | c.9171A>T p.R3057S | Missense Mutation (SNP) | VAF 31/359 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2
- WDR20 | c.287A>T p.Y96F | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); called by muse, mutect2
- YME1L1 | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 62/812 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.071); called by muse, mutect2
- ZFP90 | c.61G>T p.V21L | Missense Mutation (SNP) | VAF 43/378 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF135 | c.391G>A p.G131S (on ENST00000313434 / NM_001289401.2; = p.G143S on NM_003436.4) | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.052); called by muse, mutect2
- ZNF138 | c.686G>T p.G229V (on ENST00000307355 / NM_001367572.1; = p.G203V on NM_006524.4) | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF324B | c.1502G>T p.R501M | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ZNF426 | c.671T>G p.F224C | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ZNF567 | c.1211A>T p.Q404L (on ENST00000536254 / NM_001322913.1; = p.Q373L on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/308 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.16); called by muse, mutect2
- AP3D1 | c.1824C>T p.A608= | Silent (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- ASXL3 | c.4437C>A p.T1479= | Silent (SNP) | VAF 11/337 reads (3%) | called by muse, mutect2
- B4GALT1 | c.1191G>T p.P397= | Silent (SNP) | VAF 84/820 reads (10%) | catalogued as COSV65707474; called by muse, mutect2, varscan2
- BEND6 | c.411C>T p.N137= | Silent (SNP) | VAF 54/816 reads (7%) | called by muse, mutect2
- BRINP3 | c.879C>A p.S293= | Silent (SNP) | VAF 51/414 reads (12%) | catalogued as COSV66518115; called by muse, mutect2, varscan2
- C1QTNF1 | c.669G>T p.A223= | Silent (SNP) | VAF 20/107 reads (19%) | called by muse, mutect2, varscan2
- C4orf54 | c.2931G>C p.G977= | Silent (SNP) | VAF 27/274 reads (10%) | called by muse, mutect2
- C9orf57 | c.213C>A p.V71= (on ENST00000377024 / NM_001371610.1; = p.V49= on NM_001128618.2) | Silent (SNP) | VAF 33/477 reads (7%) | called by muse, mutect2
- CACNG7 | c.147G>A p.E49= | Silent (SNP) | VAF 22/151 reads (15%) | catalogued as COSV55817615; called by muse, mutect2, varscan2
- CCDC106 | c.87A>T p.L29= | Silent (SNP) | VAF 39/457 reads (9%) | called by muse, mutect2
- CEP152 | c.4563T>C p.H1521= (on ENST00000380950 / NM_001194998.2; = p.H1465= on NM_014985.4) | Silent (SNP) | VAF 75/744 reads (10%) | catalogued as rs769990157; called by muse, mutect2
- CNTRL | c.687A>T p.P229= | Silent (SNP) | VAF 54/420 reads (13%) | called by muse, mutect2, varscan2
- COL6A5 | c.5232T>C p.H1744= | Silent (SNP) | VAF 43/503 reads (9%) | catalogued as rs1219963448; called by muse, mutect2
- CTDP1 | c.2316G>T p.R772= | Silent (SNP) | VAF 22/550 reads (4%) | catalogued as COSV50005608; called by muse, mutect2
- CTSH | c.12G>T p.T4= | Silent (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2, varscan2
- DAAM2 | c.913C>T p.L305= | Silent (SNP) | VAF 16/462 reads (3%) | called by muse, mutect2
- DCAF12L1 | c.1132C>A p.R378= | Silent (SNP) | VAF 22/111 reads (20%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.957C>T p.P319= | Silent (SNP) | VAF 37/331 reads (11%) | catalogued as rs143361209; called by muse, mutect2, varscan2
- DMRT1 | c.615A>T p.S205= | Silent (SNP) | VAF 72/525 reads (14%) | called by muse, mutect2, varscan2
- DNAAF4 | c.936A>T p.A312= | Silent (SNP) | VAF 24/360 reads (7%) | called by muse, mutect2
- FAM114A2 | c.1140G>T p.R380= | Silent (SNP) | VAF 42/438 reads (10%) | called by muse, mutect2
- FAM47A | c.2292T>G p.T764= | Silent (SNP) | VAF 12/190 reads (6%) | catalogued as COSV100649725, COSV60493933; called by muse, mutect2
- FUT10 | c.1272A>C p.T424= | Silent (SNP) | VAF 28/547 reads (5%) | catalogued as rs1198689872; called by muse, mutect2
- GABRA2 | c.334C>A p.R112= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as rs1196569903, COSV62915947, COSV62920750; called by muse, mutect2, varscan2
- GALNT17 | c.186G>A p.A62= | Silent (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- IKZF4 | c.423G>A p.G141= | Silent (SNP) | VAF 28/133 reads (21%) | called by muse, mutect2, varscan2
- INSC | c.1041G>T p.V347= | Silent (SNP) | VAF 15/273 reads (5%) | catalogued as rs1204002673, COSV65412759; called by muse, mutect2
- KIF4B | c.3195T>C p.D1065= | Silent (SNP) | VAF 76/791 reads (10%) | called by muse, mutect2
- LRRC10 | c.468G>T p.L156= | Silent (SNP) | VAF 22/450 reads (5%) | called by muse, mutect2
- LRRC23 | c.603G>A p.K201= | Silent (SNP) | VAF 20/755 reads (3%) | catalogued as COSV50394671; called by muse, mutect2
- MFSD13A | c.330G>T p.A110= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as rs745623388, COSV53268290; called by muse, mutect2, varscan2
- MUC16 | c.36274C>A p.R12092= | Silent (SNP) | VAF 33/325 reads (10%) | catalogued as rs751199072; called by muse, mutect2, varscan2
- MUC5AC | c.1218G>A p.G406= | Silent (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- MYH6 | c.4407G>T p.L1469= | Silent (SNP) | VAF 22/328 reads (7%) | called by muse, mutect2
- MYO9A | c.552A>T p.I184= | Silent (SNP) | VAF 20/216 reads (9%) | catalogued as COSV61853794; called by muse, mutect2
- NCALD | c.279G>C p.S93= | Silent (SNP) | VAF 44/366 reads (12%) | catalogued as rs750436141; called by muse, mutect2, varscan2
- NLRP2 | c.1167G>T p.A389= | Silent (SNP) | VAF 36/252 reads (14%) | catalogued as rs759650015, COSV54757131; called by mutect2, varscan2
- NOL4 | c.1890G>T p.L630= | Silent (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- NR3C1 | c.1347G>T p.V449= | Silent (SNP) | VAF 46/648 reads (7%) | called by muse, mutect2
- NTRK3 | c.1245C>A p.P415= | Silent (SNP) | VAF 129/1429 reads (9%) | called by muse, mutect2
- NUP98 | c.5265G>A p.L1755= (on ENST00000359171 / NM_001365126.1; = p.L1738= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 20/350 reads (6%) | called by muse, mutect2
- OR2AG2 | c.765C>A p.A255= | Silent (SNP) | VAF 12/201 reads (6%) | called by muse, mutect2
- OR5L2 | c.348C>A p.A116= | Silent (SNP) | VAF 30/218 reads (14%) | catalogued as COSV65723491; called by muse, mutect2, varscan2
- OR6K3 | c.816C>A p.L272= (on ENST00000368146; = p.L256= on NM_001005327.2) | Silent (SNP) | VAF 28/326 reads (9%) | called by muse, mutect2
- PDZD8 | c.3348A>T p.I1116= | Silent (SNP) | VAF 32/522 reads (6%) | called by muse, mutect2
- PIBF1 | c.180T>C p.I60= | Silent (SNP) | VAF 14/478 reads (3%) | called by muse, mutect2
- PPP4R2 | c.870T>C p.R290= | Silent (SNP) | VAF 40/380 reads (11%) | called by muse, varscan2
- PTCH1 | c.765G>A p.R255= | Silent (SNP) | VAF 120/936 reads (13%) | called by muse, mutect2, varscan2
- PTPN1 | c.630C>T p.P210= | Silent (SNP) | VAF 44/538 reads (8%) | catalogued as rs745951097, COSV100860568; called by muse, mutect2
- PYDC2 | c.165G>C p.L55= | Silent (SNP) | VAF 44/590 reads (7%) | called by muse, mutect2
- RYR3 | c.3051C>A p.P1017= | Silent (SNP) | VAF 62/469 reads (13%) | called by muse, mutect2, varscan2
- SLC25A11 | c.78G>T p.L26= | Silent (SNP) | VAF 24/288 reads (8%) | called by muse, mutect2
- TCF25 | c.1086G>A p.T362= | Silent (SNP) | VAF 15/206 reads (7%) | catalogued as rs768359395, COSV104373234; called by muse, mutect2
- TRIM41 | c.228G>T p.V76= | Silent (SNP) | VAF 24/274 reads (9%) | catalogued as COSV100162949; called by muse, mutect2
- UMOD | c.1125G>C p.R375= | Silent (SNP) | VAF 33/396 reads (8%) | catalogued as COSV56778553; called by muse, mutect2
- UNC13A | c.1329C>A p.S443= | Silent (SNP) | VAF 20/159 reads (13%) | called by muse, mutect2, varscan2
- UNC13C | c.996A>G p.E332= | Silent (SNP) | VAF 17/149 reads (11%) | called by muse, mutect2, varscan2
- UNC80 | c.1611C>A p.A537= | Silent (SNP) | VAF 25/479 reads (5%) | called by muse, mutect2
- USH2A | c.12942G>T p.V4314= | Silent (SNP) | VAF 45/879 reads (5%) | called by muse, mutect2
- WDR7 | c.4200G>T p.V1400= | Silent (SNP) | VAF 24/577 reads (4%) | called by muse, mutect2
- ABCA1 | c.-20G>T | 5'UTR (SNP) | VAF 72/450 reads (16%) | catalogued as rs1467080859; called by muse, mutect2, varscan2
- AC092865.4 | chr12:8390653 G>T | 5'Flank (SNP) | VAF 8/33 reads (24%) | catalogued as rs190105354; called by muse, mutect2
- AC104389.6 | c.*35G>T | 3'UTR (SNP) | VAF 40/374 reads (11%) | called by muse, mutect2, varscan2
- ADGRL3 | chr4:62071784 C>A | 3'Flank (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- AFF3 | chr2:100105679 G>C | 5'Flank (SNP) | VAF 41/530 reads (8%) | called by muse, mutect2
- AGBL3 | c.311-6980A>T | Intron (SNP) | VAF 15/170 reads (9%) | called by muse, mutect2
- AL732372.2 | n.151+2494del | Intron (DEL) | VAF 38/164 reads (23%) | called by mutect2, varscan2
- ALDH16A1 | c.759+10G>T | Intron (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- ANKRD20A5P | n.164G>T | RNA (SNP) | VAF 13/141 reads (9%) | catalogued as rs142779176; called by muse, mutect2
- CACNA1G | c.4422+241G>T | Intron (SNP) | VAF 10/43 reads (23%) | called by muse, varscan2
- CCDC144CP | n.2110G>T | RNA (SNP) | VAF 20/254 reads (8%) | catalogued as rs759821539; called by muse, mutect2
- CCL13 | c.*9A>T | 3'UTR (SNP) | VAF 65/726 reads (9%) | called by muse, mutect2
- CHRND | chr2:232526129 C>A | 5'Flank (SNP) | VAF 16/123 reads (13%) | catalogued as rs752197775; called by muse, mutect2, varscan2
- CLEC1A | c.116-3247G>C | Intron (SNP) | VAF 19/156 reads (12%) | called by muse, mutect2, varscan2
- CLUHP11 | n.214C>T | RNA (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- COL6A4P1 | n.208G>T | RNA (SNP) | VAF 70/856 reads (8%) | called by muse, mutect2
- COLEC11 | chr2:3594971 G>T | 5'Flank (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- DENND3 | c.383+1115A>T | Intron (SNP) | VAF 32/227 reads (14%) | called by muse, mutect2, varscan2
- EGFEM1P | n.562G>C | RNA (SNP) | VAF 22/168 reads (13%) | called by muse, mutect2, varscan2
- EXOC3L4 | chr14:103110374 C>T | 3'Flank (SNP) | VAF 11/182 reads (6%) | called by muse, mutect2
- FRMD8P1 | n.1069G>T | RNA (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- FXR1 | c.51+2842G>C | Intron (SNP) | VAF 49/570 reads (9%) | called by muse, mutect2
- GCNT2 | c.926-35180G>A | Intron (SNP) | VAF 112/1300 reads (9%) | catalogued as rs1214940977; called by muse, mutect2
- GIMAP6 | c.86-136T>C | Intron (SNP) | VAF 11/130 reads (8%) | called by muse, mutect2
- HERC2P2 | n.2152C>T | RNA (SNP) | VAF 83/679 reads (12%) | called by muse, mutect2, varscan2
- IGKV2-29 | n.304C>A | RNA (SNP) | VAF 53/457 reads (12%) | catalogued as rs558900824; called by muse, mutect2, varscan2
- KARS1 | c.-14G>T | 5'UTR (SNP) | VAF 31/548 reads (6%) | catalogued as COSV100093616; called by muse, mutect2
- KIAA0895 | c.868-994G>A | Intron (SNP) | VAF 18/265 reads (7%) | called by muse, mutect2
- KRT8P11 | n.1005C>G | RNA (SNP) | VAF 36/242 reads (15%) | catalogued as rs1329978058; called by muse, mutect2, varscan2
- LINC00632 | n.104+1935C>G | Intron (SNP) | VAF 60/353 reads (17%) | called by muse, mutect2, varscan2
- LTBP4 | c.2758+23G>T | Intron (SNP) | VAF 56/236 reads (24%) | catalogued as rs1286914141; called by muse, mutect2, varscan2
- OR6W1P | n.394C>A | RNA (SNP) | VAF 25/215 reads (12%) | catalogued as rs981959755; called by muse, mutect2, varscan2
- PDLIM3 | c.93+10236C>A | Intron (SNP) | VAF 53/790 reads (7%) | called by muse, mutect2
- PHLDB2 | c.1335+145G>T | Intron (SNP) | VAF 44/454 reads (10%) | catalogued as COSV101208710; called by muse, mutect2
- PRKAG2 | c.466+45222_466+45230del | Intron (DEL) | VAF 28/273 reads (10%) | called by mutect2, pindel
- PRKCG | c.-131C>A | 5'UTR (SNP) | VAF 8/38 reads (21%) | called by muse, varscan2
- RANBP1 | c.310+159A>T | Intron (SNP) | VAF 43/354 reads (12%) | called by muse, mutect2, varscan2
- RGS4 | c.-52C>A | 5'UTR (SNP) | VAF 78/693 reads (11%) | called by muse, mutect2, varscan2
- RPS4XP21 | n.389T>A | RNA (SNP) | VAF 126/411 reads (31%) | called by muse, mutect2, varscan2
- SLC20A2 | c.289+936C>T | Intron (SNP) | VAF 26/365 reads (7%) | catalogued as rs993479875, COSV60602360; called by muse, mutect2
- SLITRK2 | chrX:145827930 C>A | 3'Flank (SNP) | VAF 42/178 reads (24%) | called by muse, mutect2, varscan2
- SNORD115-16 | n.59C>A | RNA (SNP) | VAF 32/590 reads (5%) | called by muse, mutect2
- SORBS3 | c.1954+955G>T | Intron (SNP) | VAF 32/335 reads (10%) | called by muse, mutect2
- SPAG6 | c.25+32G>T | Intron (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- SPRR2C | n.67C>A | RNA (SNP) | VAF 18/370 reads (5%) | called by muse, mutect2
- TEX101 | c.-15T>A | 5'UTR (SNP) | VAF 71/255 reads (28%) | called by muse, mutect2, varscan2
- TMEM135 | c.*6443G>T | 3'UTR (SNP) | VAF 60/592 reads (10%) | called by muse, mutect2
- UBE2D4 | c.-76G>C | 5'UTR (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
